MMRF case MMRF_2050 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/9fb458b7-e7b4-4052-9da9-ddb2f6ef2463

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 78 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 78.5 years (28,675 days); ISS stage: III; Days to last known disease status: 164 days; Days to last follow up: 164 days.
   Treatment given: Therapeutic agents: Bortezomib + Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 4.73 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 890 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 55.3 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 11.8 µg/mL; Lactate Dehydrogenase 4.8 µkat/L; Hemoglobin 5.93 mmol/L; Leukocytes 6.59 ×10⁹/L; Absolute Neutrophil 3.82 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 17.9 mmol/L; Calcium 2.35 mmol/L; Albumin 32.9 g/L; Total Protein 12.6 g/dL; Glucose 5.78 mmol/L; C-Reactive Protein 0.33 mg/dL.
- Day 95 (ECOG 1): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.8 mg/dL; Immunoglobulin G 4.91 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 4.11 µg/mL; Lactate Dehydrogenase 3.97 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.55 ×10⁹/L; Absolute Neutrophil 3.82 ×10⁹/L; Platelets 73.5 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 15.4 mmol/L; Calcium 2.05 mmol/L; Albumin 39.6 g/L; Total Protein 6.14 g/dL; Glucose 5.56 mmol/L.
- Day 164 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.01 mg/dL; Immunoglobulin G 2.75 g/L; Immunoglobulin A 0.31 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 6.38 µkat/L; Hemoglobin 5.97 mmol/L; Leukocytes 4.14 ×10⁹/L; Absolute Neutrophil 3.48 ×10⁹/L; Platelets 20.7 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 0.964 mmol/L; Calcium 2.1 mmol/L; Albumin 35 g/L; Total Protein 5.24 g/dL; Glucose 6.99 mmol/L.

Other clinical attributes
- Day -5: Weight: 72 kg; Height: 155 cm.

Biospecimens (2 samples)
- Sample MMRF_2050_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_2050_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
